Somatic mutation profile of tumor specimen TCGA-43-8118-01A (aliquot TCGA-43-8118-01A-11D-2395-08) from TCGA case TCGA-43-8118, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 55.4 years (20,224 days).
Specimen TCGA-43-8118-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52c35c11-b7a9-4393-9d63-e42ef847633b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-8118-10A (Blood Derived Normal), aliquot TCGA-43-8118-10A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf8be57f-bdaf-44dc-a100-a305e070f748

The open-access MAF lists 669 somatic variants for this specimen: 511 protein-altering or splice-affecting, 136 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 446, Silent 136, Nonsense Mutation 39, Splice Site 10, Intron 9, RNA 8, Frame Shift Del 6, Splice Region 5, 3'Flank 2, In Frame Del 2, 5'UTR 2, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STAT3 | c.1846G>C p.E616Q | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs1064794899, COSV52885605, COSV52886728; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.376T>C p.Y126H | Missense Mutation (SNP) | VAF 18/47 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM118879, COSV52661802, COSV52809424, COSV53031989, COSV53515469; called by muse, mutect2, varscan2
- A2M | c.2632G>C p.E878Q | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100588999; called by muse, mutect2, varscan2
- AASDH | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as COSV99221825; called by muse, mutect2, varscan2
- ABCA13 | c.13063G>T p.E4355* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV101291428; called by muse, mutect2, varscan2
- ABCA6 | c.1269T>A p.Y423* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99447622; called by muse, mutect2, varscan2
- ABCB1 | c.1101G>T p.K367N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99711755; called by muse, mutect2, varscan2
- ABCC8 | c.2886G>T p.R962S | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.253); catalogued as COSV100217709; called by muse, mutect2
- ABCD1 | c.1333G>T p.A445S | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1569541015, COSV99497903; called by muse, mutect2, varscan2
- ACVR1C | c.199C>A p.P67T | Missense Mutation (SNP) | VAF 39/337 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV54645427, COSV54650061, COSV99695034; called by muse, mutect2, varscan2
- ADAM19 | c.1131G>A p.G377= | Splice Region (SNP) | VAF 19/77 reads (25%) | catalogued as COSV99978404; called by muse, mutect2, varscan2
- ADAMTS17 | c.533A>T p.H178L | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99171571; called by muse, mutect2, varscan2
- ADCY10 | c.3769G>T p.D1257Y | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100897077; called by muse, mutect2, varscan2
- ADGRA2 | c.1903C>A p.P635T | Missense Mutation (SNP) | VAF 84/340 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.861); catalogued as COSV100178400; called by muse, mutect2, varscan2
- ADGRL2 | c.2006-2A>T p.X669_splice (on ENST00000370717 / NM_001366005.1; = p.X656_splice on NM_012302.4) | Splice Site (SNP) | VAF 14/170 reads (8%) | catalogued as COSV99591421; called by muse, mutect2
- ADGRL3 | c.1589G>C p.R530T (on ENST00000506720 / NM_001322402.2; = p.R462T on NM_015236.6) | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV101547383; called by muse, mutect2, varscan2
- ADGRV1 | c.12160T>A p.S4054T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as COSV101316461; called by muse, mutect2, varscan2
- AGTR1 | c.720G>T p.K240N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs375320868; called by muse, mutect2, varscan2
- AHCYL2 | c.1657G>T p.A553S | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.502); catalogued as COSV100273731; called by muse, mutect2, varscan2
- AHNAK | c.15760G>T p.E5254* | Nonsense Mutation (SNP) | VAF 39/173 reads (23%) | catalogued as COSV99949482; called by muse, mutect2, varscan2
- AKAP12 | c.942G>T p.R314S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV99484374; called by muse, mutect2, varscan2
- AKAP13 | c.8163G>C p.L2721F (on ENST00000394518 / NM_007200.5; = p.L2725F on NM_006738.6) | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as COSV100774578; called by muse, mutect2
- AKIP1 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100214967; called by muse, mutect2, varscan2
- ALB | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99892180; called by muse, mutect2, varscan2
- ALMS1 | c.11572G>A p.D3858N | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100043609; called by muse, mutect2, varscan2
- ALPK2 | c.4807C>T p.P1603S | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64492569; called by muse, mutect2, varscan2
- AMBN | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100534480; called by muse, mutect2, varscan2
- AMOT | c.1930C>T p.Q644* (on ENST00000371959 / NM_001113490.1; = p.Q235* on NM_133265.3) | Nonsense Mutation (SNP) | VAF 22/127 reads (17%) | catalogued as COSV100495529; called by muse, mutect2, varscan2
- ANK2 | c.2077A>G p.K693E | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100004081; called by muse, mutect2, varscan2
- ANKAR | c.677A>T p.D226V | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV99854615; called by muse, mutect2, varscan2
- ANKFN1 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1385079893, COSV59451574; called by muse, mutect2
- AP1B1 | c.247A>T p.M83L | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.706); catalogued as COSV100434793; called by muse, mutect2, varscan2
- AP1G1 | c.1952C>T p.S651F | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as COSV55492520; called by muse, mutect2, varscan2
- APBB1 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100194306; called by muse, mutect2, varscan2
- APBB1IP | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100774471; called by muse, mutect2
- APP | c.550T>C p.F184L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100696243; called by muse, mutect2
- ARHGAP33 | c.1786G>C p.A596P | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.086); catalogued as COSV99139906; called by muse, mutect2, varscan2
- ARHGEF11 | c.3466G>T p.A1156S | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.022); catalogued as COSV100168939; called by muse, mutect2, varscan2
- ARHGEF12 | c.4442G>T p.G1481V | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.261); catalogued as COSV100755197; called by muse, mutect2, varscan2
- ARID5B | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV99690398; called by muse, mutect2
- ARMH4 | c.1102G>T p.G368W | Missense Mutation (SNP) | VAF 83/282 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99958965; called by muse, mutect2, varscan2
- ASTN1 | c.1183G>T p.V395L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99922959; called by muse, mutect2, varscan2
- ASXL3 | c.1530A>C p.E510D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs765461709, COSV99326453; called by muse, mutect2, varscan2
- ATAD2 | c.1813A>G p.K605E | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as COSV99785256; called by muse, mutect2, varscan2
- ATP13A3 | c.1350C>G p.I450M | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99757624; called by muse, mutect2
- ATP2B3 | c.1651G>T p.V551F | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV99685774; called by muse, mutect2, varscan2
- ATP5F1B | c.1504C>G p.L502V | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.166); catalogued as COSV99467643; called by muse, mutect2
- ATR | c.4165G>A p.D1389N | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100638568; called by muse, mutect2
- ATRX | c.5336G>T p.R1779I | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100971377; called by muse, mutect2, varscan2
- BAG6 | c.2693C>T p.T898I (on ENST00000676571; = p.T851I on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1251897224, COSV99277585; called by muse, mutect2, varscan2
- BARX2 | c.826C>A p.P276T | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1217858966, COSV99859016; called by muse, mutect2, varscan2
- BBOF1 | c.1082G>C p.R361T | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV101223947; called by muse, mutect2
- BBX | c.1642A>T p.K548* | Nonsense Mutation (SNP) | VAF 113/169 reads (67%) | catalogued as COSV100362233; called by muse, mutect2, varscan2
- BCHE | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100012964; called by muse, mutect2, varscan2
- BCORL1 | c.4918C>G p.Q1640E | Missense Mutation (SNP) | VAF 49/358 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99500846; called by muse, varscan2
- BCR | c.2158G>T p.E720* | Nonsense Mutation (SNP) | VAF 3/21 reads (14%) | catalogued as COSV100007022; called by muse, mutect2
- BLK | c.1416C>A p.C472* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99377598; called by muse, mutect2, varscan2
- BRINP3 | c.733G>C p.V245L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100819415; called by muse, mutect2, varscan2
- BSN | c.11636G>A p.G3879E | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as rs1407260233, COSV99609721; called by muse, mutect2, varscan2
- C1QTNF9 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as COSV100130015; called by muse, mutect2, varscan2
- C1orf158 | c.428A>T p.Y143F | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV99847451; called by muse, mutect2, varscan2
- C2orf16 | c.1894G>A p.V632M | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs1243822911, COSV100821003; called by muse, mutect2, varscan2
- C2orf80 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.275); catalogued as COSV100378630; called by muse, mutect2, varscan2
- C4BPA | c.1346A>T p.E449V | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.1); catalogued as rs1274971250, COSV100891280; called by muse, mutect2, varscan2
- CACNG1 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 62/156 reads (40%) | catalogued as COSV99871776; called by muse, mutect2, varscan2
- CALCR | c.1299G>T p.W433C (on ENST00000649521 / NM_001164737.2; = p.W417C on NM_001742.4) | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.887); catalogued as rs529140021, COSV100810844, COSV64012245; called by muse, mutect2, varscan2
- CAMKMT | c.744G>C p.K248N | Missense Mutation (SNP) | VAF 51/393 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.951); catalogued as COSV101035456; called by muse, mutect2, varscan2
- CAPRIN1 | c.1520A>T p.N507I | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100404243; called by muse, mutect2, varscan2
- CARF | c.1831G>C p.G611R | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.259); catalogued as COSV100247883; called by muse, mutect2, varscan2
- CASZ1 | c.2548G>C p.V850L | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV100682137; called by muse, mutect2, varscan2
- CAVIN4 | c.740G>T p.R247M | Missense Mutation (SNP) | VAF 109/238 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100293386; called by muse, mutect2, varscan2
- CBFA2T2 | c.61+1G>T p.X21_splice | Splice Site (SNP) | VAF 22/84 reads (26%) | catalogued as COSV100674562; called by muse, mutect2, varscan2
- CCDC105 | c.1126G>T p.G376C | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52965716, COSV99480111; called by muse, mutect2, varscan2
- CCDC178 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55761954; called by muse, mutect2, varscan2
- CCDC33 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.701); catalogued as COSV99166171; called by muse, mutect2, varscan2
- CCDC93 | c.128G>A p.R43K | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100099433, COSV60120519; called by muse, mutect2, varscan2
- CCT8L2 | c.289C>A p.Q97K | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100742655, COSV100743098; called by muse, mutect2, varscan2
- CD101 | c.1447A>T p.N483Y | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.454); catalogued as COSV99870158; called by muse, mutect2
- CDC73 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100813982, COSV66465487; called by muse, mutect2, varscan2
- CDCP2 | c.919C>G p.P307A | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.534); catalogued as COSV100313671; called by muse, mutect2, varscan2
- CDH10 | c.2068A>T p.I690F | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100053028, COSV52596889; called by muse, mutect2, varscan2
- CDH19 | c.2224G>T p.D742Y | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100052278, COSV50977392; called by muse, mutect2, varscan2
- CDKL5 | c.286A>G p.M96V | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.825); catalogued as COSV101184450; called by muse, mutect2, varscan2
- CDX2 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.738); catalogued as COSV101122714; called by muse, mutect2, varscan2
- CEP192 | c.6346G>C p.A2116P | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV100382060; called by muse, mutect2, varscan2
- CFAP161 | c.371G>A p.R124K | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99715609; called by muse, mutect2
- CFAP94 | c.1982C>T p.A661V (on ENST00000320267 / NM_001352064.2; = p.A667V on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100209720; called by muse, mutect2, varscan2
- CFC1 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 30/207 reads (14%) | catalogued as COSV99383521; called by muse, mutect2, varscan2
- CHD5 | c.5479G>T p.A1827S | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.441); catalogued as rs778128816, COSV99314931; called by muse, mutect2, varscan2
- CHL1 | c.1693G>A p.E565K (on ENST00000397491 / NM_001253387.1; = p.E581K on NM_006614.4) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV99852264; called by muse, mutect2, varscan2
- CHRM4 | c.1340C>T p.T447I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100551941; called by muse, mutect2, varscan2
- CHST1 | c.54C>G p.I18M | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100346508; called by muse, mutect2, varscan2
- CHST8 | c.444C>A p.S148R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99381620; called by muse, mutect2, varscan2
- CHST8 | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV99381625; called by muse, mutect2, varscan2
- CILP2 | c.3368C>A p.A1123E | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV99365161; called by muse, mutect2, varscan2
- CIT | c.2077G>T p.A693S | Missense Mutation (SNP) | VAF 163/620 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as COSV99950904; called by muse, varscan2
- CLEC17A | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100355564; called by muse, mutect2, varscan2
- CLEC1A | c.627G>T p.W209C | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59531846; called by muse, mutect2, varscan2
- CLTCL1 | c.312G>T p.M104I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV99595845; called by muse, mutect2, varscan2
- CMKLR1 | c.587C>T p.S196F (on ENST00000312143 / NM_001142344.2; = p.S194F on NM_004072.3) | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs1350208182, COSV100379603; called by muse, mutect2, varscan2
- CNTN5 | c.808C>A p.L270M | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV99681061; called by muse, mutect2, varscan2
- CNTNAP5 | c.435C>A p.H145Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.697); catalogued as COSV101444186; called by muse, mutect2, varscan2
- COL11A1 | c.2144G>T p.G715V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100617970; called by muse, mutect2, varscan2
- COL1A1 | c.3186G>C p.K1062N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV99868085; called by muse, mutect2, varscan2
- COL1A1 | c.2900G>C p.R967T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99868092; called by muse, mutect2, varscan2
- COL4A1 | c.3848A>T p.K1283M | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101011561; called by muse, mutect2
- COL4A6 | c.1576C>A p.P526T | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.745); catalogued as COSV100564986; called by muse, mutect2, varscan2
- COL5A2 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV100880771; called by muse, mutect2, varscan2
- COL6A6 | c.1412A>G p.H471R | Missense Mutation (SNP) | VAF 99/216 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV100650897; called by muse, mutect2, varscan2
- CPA4 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775976932, COSV99745326; called by muse, mutect2
- CPNE2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs761204203, COSV99321600; called by muse, mutect2, varscan2
- CPS1 | c.1864G>T p.V622L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.822); catalogued as CM114328, COSV51826352, COSV99244026; called by muse, mutect2, varscan2
- CRACD | c.181A>T p.K61* | Nonsense Mutation (SNP) | VAF 14/111 reads (13%) | catalogued as COSV51723072, COSV99949966; called by muse, mutect2
- CRACD | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV99949967; called by muse, mutect2
- CREBBP | c.4550A>T p.H1517L | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.987); catalogued as COSV99271866; called by muse, mutect2, varscan2
- CSF2RB | c.49T>A p.W17R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV99454401; called by muse, mutect2, varscan2
- CSMD3 | c.2335G>T p.D779Y (on ENST00000297405 / NM_001363185.1; = p.D675Y on NM_052900.3) | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52093245, COSV52155208, COSV52228557; called by muse, mutect2, varscan2
- CSPG4 | c.5098T>A p.C1700S | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.468); catalogued as COSV100414136; called by muse, mutect2
- CSTF2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 14/96 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV100802966; called by muse, mutect2, varscan2
- CSTF2 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.003); catalogued as COSV100802922, COSV100802967; called by muse, mutect2, varscan2
- CSTF2 | c.387C>A p.S129R | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV100802968; called by muse, mutect2, varscan2
- CTAG2 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as rs1557241847, COSV99909186; called by muse, mutect2, varscan2
- CTNNA2 | c.2104G>T p.A702S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.074); catalogued as rs1196796842, COSV100561970; called by muse, mutect2, varscan2
- CTNNA3 | c.2263C>T p.Q755* | Nonsense Mutation (SNP) | VAF 20/81 reads (25%) | catalogued as COSV101041607; called by muse, mutect2, varscan2
- CTNNA3 | c.2086G>T p.D696Y | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101041524, COSV101041608; called by muse, mutect2, varscan2
- CXorf66 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100983941; called by muse, mutect2, varscan2
- CXorf66 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 48/398 reads (12%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.673); catalogued as COSV100983943; called by muse, mutect2, varscan2
- DCAF12L1 | c.1236C>A p.N412K | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100948438; called by muse, mutect2
- DCAF12L2 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1229366218, COSV63580270, COSV63581169; called by muse, mutect2, varscan2
- DDX28 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 16/115 reads (14%) | catalogued as rs1256525915, COSV100193137; called by muse, mutect2, varscan2
- DELE1 | c.147-1G>C p.X49_splice | Splice Site (SNP) | VAF 10/97 reads (10%) | catalogued as COSV99520010; called by muse, mutect2, varscan2
- DHCR7 | c.1204G>T p.V402L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV100832121; called by muse, mutect2, varscan2
- DHX15 | c.1787-2A>T p.X596_splice | Splice Site (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100391725; called by muse, mutect2, varscan2
- DKK2 | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99569461; called by muse, mutect2, varscan2
- DLG1 | c.1840C>A p.H614N | Missense Mutation (SNP) | VAF 15/228 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV100015964; called by muse, mutect2
- DMWD | c.1860C>G p.C620W | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99353653; called by muse, mutect2
- DNAH5 | c.3506T>A p.F1169Y | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV99453900; called by muse, mutect2
- DNAH7 | c.6994C>A p.Q2332K | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100417434; called by muse, mutect2, varscan2
- DNAH7 | c.6586G>C p.E2196Q | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.457); catalogued as COSV100417435; called by muse, mutect2
- DPP4 | c.1925C>G p.S642W | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100859078; called by muse, mutect2, varscan2
- DYDC1 | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV99758192; called by muse, mutect2, varscan2
- DZANK1 | c.2234G>A p.R745K (on ENST00000262547 / NM_001099407.1; = p.R552K on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1445751364, COSV99363197; called by muse, mutect2, varscan2
- EBF3 | c.848T>A p.I283K (on ENST00000355311 / NM_001375392.1; = p.I274K on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100799597; called by muse, mutect2, varscan2
- ECPAS | c.5075G>T p.S1692I | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as COSV99399257; called by muse, mutect2, varscan2
- EFL1 | c.2410A>T p.K804* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV99188523; called by muse, mutect2, varscan2
- EFL1 | c.2409C>A p.F803L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV99186693, COSV99188533; called by muse, mutect2, varscan2
- EIF5B | c.1889G>T p.R630I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99178789; called by muse, mutect2, varscan2
- ELMO3 | c.647C>T p.T216I (on ENST00000652269; = p.T163I on NM_024712.5) | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.937); catalogued as COSV100681938; called by muse, mutect2, varscan2
- ELP1 | c.153G>A p.V51= | Splice Region (SNP) | VAF 17/100 reads (17%) | catalogued as COSV100534647; called by muse, mutect2, varscan2
- EPB42 | c.549+1G>T p.X183_splice (on ENST00000441366 / NM_001114134.2; = p.X213_splice on NM_000119.3) | Splice Site (SNP) | VAF 14/100 reads (14%) | catalogued as COSV100282133; called by muse, mutect2, varscan2
- EPHA5 | c.831C>G p.S277R | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV99901104; called by muse, mutect2, varscan2
- EPHA6 | c.1425C>G p.D475E | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.054); catalogued as COSV101065362; called by muse, mutect2, varscan2
- ERBB2 | c.3160-1G>A p.X1054_splice | Splice Site (SNP) | VAF 14/242 reads (6%) | catalogued as COSV54062705, COSV99509014; called by muse, mutect2
- ERBB4 | c.237T>A p.S79= | Splice Region (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99632225; called by muse, mutect2
- EXT2 | c.1743G>T p.K581N (on ENST00000343631; = p.K614N on NM_000401.3) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100640689; called by muse, mutect2, varscan2
- FAHD1 | c.567G>C p.L189F | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147870961, COSV101232558; called by muse, mutect2, varscan2
- FAM153B | c.1058T>A p.V353E (on ENST00000253490; = p.V276E on NM_001265615.1) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); catalogued as COSV99499134; called by mutect2, varscan2
- FAM160B1 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | catalogued as COSV100985190; called by muse, mutect2, varscan2
- FAM3D | c.194A>G p.Y65C | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs758879825, COSV100717006; called by muse, mutect2, varscan2
- FAM47A | c.1811C>T p.T604I | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100650061, COSV60497884; called by muse, mutect2, varscan2
- FAT2 | c.6034_6042del p.F2012_M2014del | In Frame Del (DEL) | VAF 42/157 reads (27%) | catalogued as rs774846153; called by mutect2, pindel, varscan2
- FBLN5 | c.992G>T p.R331L | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV50903339, COSV99969920; called by muse, mutect2, varscan2
- FGF21 | c.584G>T p.S195I | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99711547; called by muse, mutect2, varscan2
- FILIP1 | c.2616G>T p.W872C | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.214); catalogued as COSV99386078; called by muse, mutect2, varscan2
- FIP1L1 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 21/108 reads (19%) | catalogued as COSV100184712, COSV60996249; called by muse, mutect2, varscan2
- FLG2 | c.1373C>A p.S458Y | Missense Mutation (SNP) | VAF 77/286 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as COSV66168481, COSV66173971; called by muse, mutect2, varscan2
- FLNA | c.3081C>A p.D1027E | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.029); catalogued as COSV100775213; called by muse, mutect2, varscan2
- FLNC | c.5012A>T p.K1671M | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100368698; called by muse, mutect2, varscan2
- FLT3 | c.1992G>A p.M664I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV54046071, COSV54047442, COSV54051809; called by muse, mutect2, varscan2
- FMN2 | c.1690C>G p.R564G | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs147501995; called by muse, mutect2, varscan2
- FMOD | c.166G>T p.G56W | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as rs773564439, COSV100724627; called by muse, mutect2, varscan2
- FRAS1 | c.8029G>T p.E2677* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99355666; called by muse, mutect2, varscan2
- GABRA2 | c.280C>G p.R94G | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100734734, COSV62915909; called by muse, mutect2
- GALNT17 | c.715G>T p.G239W | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100352861, COSV61160299; called by muse, mutect2, varscan2
- GATA3 | c.1294C>A p.P432T | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.188); catalogued as COSV100651227; called by muse, mutect2, varscan2
- GDPGP1 | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs756419713, COSV100292133; called by muse, mutect2, varscan2
- GLI1 | c.2594A>G p.Y865C | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1372410554, COSV99954672; called by muse, mutect2, varscan2
- GLIPR1L2 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100248784; called by muse, mutect2, varscan2
- GLUD2 | c.1466C>A p.P489H | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100047086, COSV60151937; called by muse, mutect2, varscan2
- GNL3L | c.17A>G p.H6R | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1387890381, COSV60575995; called by muse, mutect2, varscan2
- GPR32 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.697); catalogued as COSV99567374; called by muse, mutect2, varscan2
- GRAMD1C | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.204); catalogued as rs1228330066, COSV100822994; called by muse, mutect2, varscan2
- GRIN2B | c.2312G>T p.G771V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.309); catalogued as COSV101663181; called by muse, mutect2, varscan2
- GRIN3A | c.2686T>A p.S896T | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV100701807; called by muse, mutect2, varscan2
- GRM5 | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100554381; called by muse, mutect2
- GSE1 | c.1837G>C p.E613Q | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV99497166; called by muse, mutect2, varscan2
- HBG2 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 16/132 reads (12%) | catalogued as COSV100400695; called by muse, varscan2
- HCFC1 | c.2684C>A p.A895D | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV100129824; called by muse, mutect2
- HCN4 | c.1601T>A p.V534E | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355950041, COSV56084079, COSV99984197; called by muse, mutect2, varscan2
- HEATR3 | c.885G>C p.M295I | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.182); catalogued as COSV53529853, COSV99590109; called by muse, mutect2, varscan2
- HECTD1 | c.2442G>T p.W814C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101237506; called by muse, mutect2, varscan2
- HEPH | c.1498G>C p.D500H (on ENST00000343002; = p.D233H on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100295656; called by muse, mutect2
- HIVEP3 | c.5053A>C p.M1685L | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV99913924; called by muse, mutect2, varscan2
- HNF1A | c.647A>T p.Q216L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV99982976; called by muse, mutect2, varscan2
- HNF4G | c.868C>G p.L290V (on ENST00000354370 / NM_001330561.2; = p.L337V on NM_004133.5) | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100585004, COSV62966870; called by muse, mutect2, varscan2
- HNRNPA1 | c.884G>C p.G295A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as COSV99267859; called by muse, mutect2
- HPRT1 | c.38A>G p.D13G | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV100053302; called by muse, mutect2
- HTR2A | c.1277T>C p.M426T | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV101096851; called by muse, mutect2, varscan2
- HUS1 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as rs567292691, COSV99346568; called by muse, mutect2, varscan2
- HYAL3 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as COSV100269810, COSV60187288; called by muse, mutect2, varscan2
- IDO2 | c.367G>T p.G123W (on ENST00000389060; = p.G136W on NM_194294.2) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58424714; called by muse, mutect2
- IGKV5-2 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1431365801; called by muse, mutect2, varscan2
- IGSF6 | c.58T>C p.F20L | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99193662; called by muse, mutect2, varscan2
- IL16 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 73/282 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV100267822; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1129T>A p.C377S | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100781923; called by muse, mutect2, varscan2
- IL24 | c.125T>A p.L42H | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV54320189; called by muse, mutect2, varscan2
- INTS1 | c.4433G>T p.R1478L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV101248306; called by muse, mutect2, varscan2
- INTS6L | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100878295; called by muse, mutect2, varscan2
- INTS7 | c.1792C>T p.H598Y | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.083); catalogued as COSV65345570; called by muse, mutect2
- IRF6 | c.819G>T p.Q273H | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM133867, COSV100884033; called by muse, mutect2, varscan2
- IRX6 | c.504C>A p.H168Q | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51859768; called by muse, mutect2, varscan2
- IRX6 | c.505C>A p.R169S | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51861788, COSV99306447; called by muse, mutect2, varscan2
- ITIH5 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs368025989; called by muse, mutect2, varscan2
- ITIH6 | c.3137A>T p.E1046V | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV99513943; called by muse, mutect2, varscan2
- JAKMIP1 | c.251T>G p.L84R | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV99290669, COSV99290704; called by muse, mutect2
- JMJD1C | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV101232471; called by muse, mutect2, varscan2
- KCNE3 | c.126G>T p.Q42H | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs752253389, COSV100035695, COSV59551952; called by muse, mutect2, varscan2
- KCNH7 | c.1998C>G p.I666M | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100037661; called by muse, mutect2
- KCNK18 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1461857136, COSV100572134; called by muse, mutect2, varscan2
- KHSRP | c.780G>T p.Q260H | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101231246; called by muse, mutect2, varscan2
- KIAA1109 | c.1427C>T p.T476I | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV99174959; called by muse, mutect2, varscan2
- KIAA1755 | c.2418-1G>A p.X806_splice | Splice Site (SNP) | VAF 29/263 reads (11%) | catalogued as COSV99642657; called by muse, mutect2, varscan2
- KIR2DL4 | c.304T>A p.Y102N (on ENST00000396284; = p.Y63N on NM_001080770.2) | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV100610708, COSV60878723; called by muse, varscan2
- KLB | c.1071A>T p.E357D | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV99962457; called by muse, mutect2, varscan2
- KLC2 | c.868G>C p.V290L | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100270870; called by muse, mutect2, varscan2
- KLF15 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs983434622, COSV56179511; called by muse, mutect2
- KLHDC10 | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100111038; called by muse, mutect2, varscan2
- KLHL34 | c.50C>T p.T17I | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV101069994; called by muse, mutect2, varscan2
- KMT2A | c.8014A>G p.S2672G | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV100629778; called by muse, mutect2, varscan2
- KMT2B | c.1679C>T p.S560L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs368369291; called by muse, mutect2
- KMT2E | c.4181A>T p.H1394L | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV99996956; called by muse, mutect2, varscan2
- KNDC1 | c.3580-2A>T p.X1194_splice | Splice Site (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100466144; called by muse, mutect2
- KNDC1 | c.3724G>T p.G1242C | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100466147; called by muse, mutect2, varscan2
- KRT24 | c.804G>C p.Q268H | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV52880134, COSV99232149; called by muse, mutect2
- KRT27 | c.151G>T p.G51C | Missense Mutation (SNP) | VAF 69/125 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs1020125782, COSV100053368; called by muse, mutect2, varscan2
- KRT71 | c.987G>T p.E329D | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99922394; called by muse, mutect2, varscan2
- KRTAP23-1 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 9/84 reads (11%) | PolyPhen benign (0.083); catalogued as COSV100492661; called by muse, mutect2, varscan2
- LAMA1 | c.3677A>G p.Q1226R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.34); catalogued as rs1327133723, COSV67532590; called by muse, mutect2
- LARP1 | c.2996A>T p.Y999F (on ENST00000518297 / NM_033551.3; = p.Y922F on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100304066; called by muse, mutect2, varscan2
- LCT | c.3972G>T p.W1324C | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51549319; called by muse, mutect2
- LCT | c.3971G>T p.W1324L | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99930377; called by muse, mutect2
- LDB2 | c.347T>A p.I116N | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100454742; called by muse, mutect2, varscan2
- LHFPL1 | c.150C>A p.C50* | Nonsense Mutation (SNP) | VAF 23/250 reads (9%) | catalogued as COSV100914517; called by muse, mutect2
- LINGO1 | c.673C>A p.L225I | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV100796505; called by muse, mutect2, varscan2
- LIPF | c.126G>T p.W42C | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99490615; called by muse, mutect2, varscan2
- LMBRD2 | c.638A>G p.Y213C | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99683247; called by muse, mutect2, varscan2
- LRBA | c.2119C>A p.H707N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.874); catalogued as COSV100842070; called by muse, mutect2, varscan2
- LRIT1 | c.1682A>G p.N561S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100928151; called by muse, mutect2, varscan2
- LRP1 | c.1850A>G p.Y617C | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99677134; called by muse, mutect2, varscan2
- LRP1B | c.8486A>T p.D2829V | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101260543; called by muse, mutect2, varscan2
- LRRC3 | c.704G>A p.R235K | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as COSV99381840; called by muse, mutect2, varscan2
- LRRK2 | c.743G>C p.R248T | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100111095; called by muse, mutect2, varscan2
- LRRK2 | c.6428G>T p.R2143L | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as CM081689, COSV100111097; called by muse, mutect2, varscan2
- LYPD5 | c.671G>T p.S224I (on ENST00000377950 / NM_001031749.3; = p.S181I on NM_182573.2) | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV100935295; called by muse, mutect2, varscan2
- MAGEE1 | c.2792A>T p.Q931L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100819516; called by muse, mutect2, varscan2
- MAP10 | c.1633G>T p.V545F | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV101406558; called by muse, mutect2
- MAP3K21 | c.1808G>T p.R603I | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV100786119, COSV100786160; called by muse, mutect2
- MAP3K3 | c.437A>G p.Q146R | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100675632; called by muse, mutect2, varscan2
- MARCHF4 | c.730G>C p.G244R | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99814093, COSV99814773; called by muse, mutect2, varscan2
- MCF2 | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV100645134; called by muse, mutect2, varscan2
- MCHR1 | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99967895; called by muse, mutect2, varscan2
- MECOM | c.1090G>T p.G364W (on ENST00000468789 / NM_001105078.4; = p.G552W on NM_004991.4) | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs746379599, COSV99245313; called by muse, mutect2, varscan2
- MED12L | c.4444A>G p.R1482G | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99854574; called by muse, mutect2, varscan2
- MFSD6 | c.626C>G p.S209* | Nonsense Mutation (SNP) | VAF 19/104 reads (18%) | catalogued as COSV55625970, COSV99855390; called by muse, mutect2, varscan2
- MLPH | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV99222635; called by muse, mutect2, varscan2
- MNDA | c.959T>A p.M320K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV100933435; called by muse, mutect2, varscan2
- MRPL32 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99786002; called by muse, mutect2
- MRPL47 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 107/214 reads (50%) | catalogued as COSV99373059; called by muse, mutect2, varscan2
- MS4A10 | c.283C>G p.P95A | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100382424, COSV57632890; called by muse, mutect2, varscan2
- MS4A8 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.409); catalogued as rs560863829, COSV55753313; called by muse, mutect2, varscan2
- MTFMT | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.326); catalogued as COSV99584516; called by muse, mutect2
- MTR | c.1819A>T p.M607L | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100855540; called by muse, mutect2, varscan2
- MTRES1 | c.146A>C p.K49T | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as COSV100261229; called by muse, mutect2, varscan2
- MTRR | c.904C>G p.Q302E (on ENST00000264668; = p.Q275E on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.019); catalogued as COSV52943581; called by muse, mutect2, varscan2
- MUC21 | c.1426G>T p.V476L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs952663767, COSV100888921; called by muse, mutect2, varscan2
- MYBBP1A | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV99626894; called by muse, mutect2, varscan2
- MYH15 | c.180G>C p.E60D | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV99844247; called by muse, mutect2
- MYH2 | c.3060G>T p.E1020D | Missense Mutation (SNP) | VAF 91/253 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV99820913; called by muse, mutect2, varscan2
- MYH4 | c.5716G>C p.E1906Q | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99702179; called by muse, mutect2
- MYH7 | c.5261A>C p.K1754T | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100806589; called by muse, mutect2, varscan2
- MYO3A | c.2000C>A p.T667N | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV99781448; called by muse, mutect2, varscan2
- MYPN | c.3767C>G p.S1256W | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100589365, COSV100590591; called by muse, mutect2, varscan2
- NAA25 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99928006; called by muse, mutect2, varscan2
- NAV3 | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as COSV57073427; called by muse, mutect2, varscan2
- NAV3 | c.5234A>T p.K1745M | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57118405; called by muse, mutect2, varscan2
- NCAM2 | c.1496C>G p.P499R | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99525134; called by muse, mutect2, varscan2
- NCDN | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV100357621, COSV57851828; called by muse, mutect2, varscan2
- NDUFA1 | c.19C>A p.P7T | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101007107; called by muse, mutect2, varscan2
- NDUFS1 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.41); catalogued as rs745926990, COSV99261435; called by muse, mutect2, varscan2
- NIPBL | c.6277G>T p.G2093* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99242534; called by muse, mutect2, varscan2
- NLGN3 | c.842G>T p.R281L (on ENST00000358741 / NM_181303.2; = p.R261L on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV100705040; called by muse, mutect2, varscan2
- NLRP12 | c.1470C>A p.D490E | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV100145863, COSV60744005; called by muse, mutect2, varscan2
- NLRP7 | c.2634G>T p.Q878H (on ENST00000340844 / NM_206828.3; = p.Q850H on NM_139176.3) | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100053339, COSV100053462; called by muse, mutect2, varscan2
- NMI | c.843A>C p.Q281H | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99693515; called by muse, mutect2, varscan2
- NPHS1 | c.709C>G p.L237V | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100800249; called by muse, mutect2
- NSUN2 | c.189G>T p.W63C | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99243454; called by muse, mutect2, varscan2
- ONECUT1 | c.961T>G p.C321G | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as COSV100009420; called by muse, mutect2, varscan2
- OPHN1 | c.1945G>T p.G649W | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as rs1278200946, COSV62782392; called by muse, mutect2, varscan2
- OR14K1 | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV99315458; called by muse, mutect2, varscan2
- OR1E2 | c.658T>C p.F220L | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.558); catalogued as COSV99943506; called by muse, mutect2, varscan2
- OR1I1 | c.347C>A p.A116E | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52917761, COSV99264908; called by muse, mutect2, varscan2
- OR2AG2 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100643172; called by muse, mutect2, varscan2
- OR2D2 | c.199T>C p.S67P | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100203926; called by muse, mutect2, varscan2
- OR2F2 | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101283853; called by muse, mutect2
- OR2T8 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100178458; called by muse, mutect2, varscan2
- OR2T8 | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100178462, COSV60664253; called by muse, mutect2, varscan2
- OR2W3 | c.417G>T p.R139S | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.41); catalogued as COSV64456332; called by muse, mutect2, varscan2
- OR4C15 | c.29A>T p.N10I | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV100115989, COSV100116084; called by muse, mutect2, varscan2
- OR4K17 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100210796; called by muse, mutect2, varscan2
- OR4K2 | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100064385; called by muse, mutect2, varscan2
- OR4N2 | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as rs754617847, COSV100269325; called by muse, mutect2, varscan2
- OR51G1 | c.529G>T p.A177S | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as COSV100429410; called by muse, mutect2, varscan2
- OR51G1 | c.356C>A p.S119Y | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100429414, COSV100429467; called by muse, mutect2, varscan2
- OR56B4 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as COSV100337699; called by muse, mutect2, varscan2
- OR5H15 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 72/355 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100736765; called by muse, mutect2, varscan2
- OR5K3 | c.347C>A p.A116E | Missense Mutation (SNP) | VAF 27/349 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs200376148, COSV101051690; called by muse, mutect2
- OR5L2 | c.58G>C p.V20L | Missense Mutation (SNP) | VAF 39/286 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.02); catalogued as COSV101004409; called by muse, mutect2, varscan2
- OR6B2 | c.935A>T p.H312L | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99401741; called by muse, mutect2, varscan2
- OR8I2 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100136256; called by muse, mutect2, varscan2
- OR8K5 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as COSV100537320, COSV57890369; called by muse, mutect2, varscan2
- OR8S1 | c.616C>G p.H206D | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as COSV100043724; called by muse, mutect2, varscan2
- OSGEPL1 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs367948883; called by muse, mutect2, varscan2
- P2RY10 | c.435G>T p.K145N | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV50682345, COSV50683308; called by muse, mutect2, varscan2
- P2RY4 | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100997051; called by muse, mutect2, varscan2
- P3H1 | c.1275G>A p.M425I | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as COSV99355549; called by muse, mutect2
- PACS1 | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.167); catalogued as COSV100270545; called by muse, mutect2
- PAM | c.2458G>T p.A820S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as COSV99173828; called by muse, mutect2, varscan2
- PANX3 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.402); catalogued as rs747132649, COSV99421806; called by muse, mutect2, varscan2
- PANX3 | c.568C>A p.P190T | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52513861, COSV99421812; called by muse, mutect2, varscan2
- PARP1 | c.1534A>G p.K512E | Missense Mutation (SNP) | VAF 39/278 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.082); catalogued as COSV100829046; called by muse, mutect2, varscan2
- PATZ1 | c.2053G>C p.E685Q | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.572); catalogued as COSV99841671; called by muse, mutect2
- PAX4 | c.633G>T p.E211D | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.149); catalogued as COSV100490331; called by muse, mutect2, varscan2
- PCDH15 | c.2947G>C p.E983Q | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.937); catalogued as COSV57301613; called by muse, mutect2, varscan2
- PCDH17 | c.2949G>T p.E983D | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100932020, COSV64978230; called by muse, mutect2, varscan2
- PCDHB5 | c.1964C>A p.A655D | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.673); catalogued as COSV99169472; called by muse, mutect2, varscan2
- PCDHGA1 | c.1883C>A p.T628K | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100966071, COSV65296718; called by muse, varscan2
- PCDHGA3 | c.1883C>A p.T628K | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV53959315, COSV54036898; called by muse, mutect2, varscan2
- PDE11A | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as rs187229119, COSV99614749; called by muse, mutect2, varscan2
- PDYN | c.286G>C p.A96P | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV99453322; called by muse, mutect2, varscan2
- PGAP1 | c.950A>T p.K317I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100698353; called by muse, mutect2, varscan2
- PGK2 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100505680; called by muse, mutect2, varscan2
- PGR | c.2474T>A p.L825* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV99679078; called by muse, mutect2, varscan2
- PHEX | c.1717G>T p.A573S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV101039999; called by muse, mutect2, varscan2
- PHF20L1 | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99622096; called by muse, mutect2, varscan2
- PIGK | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100769944; called by muse, mutect2
- PIWIL1 | c.1340C>A p.S447Y | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV99806872; called by muse, mutect2, varscan2
- PIWIL1 | c.2050A>T p.R684W | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99806875; called by muse, mutect2, varscan2
- PKD1L2 | c.2549C>G p.A850G | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.674); catalogued as rs753808208, COSV100216996; called by muse, mutect2, varscan2
- PLEKHS1 | c.856G>A p.E286K (on ENST00000369310 / NM_182601.1; = p.E292K on NM_024889.5) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as rs748290428, COSV104417353, COSV63056461; called by muse, mutect2, varscan2
- PLOD3 | c.1744G>T p.A582S | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV99778283; called by muse, mutect2, varscan2
- PLXNA2 | c.2820G>T p.E940D | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.039); catalogued as COSV100885870, COSV65438464; called by muse, mutect2, varscan2
- PLXNB3 | c.5449C>A p.P1817T | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100737890; called by muse, mutect2, varscan2
- PMEL | c.132G>C p.W44C | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100657095; called by muse, mutect2
- PMFBP1 | c.223A>T p.S75C | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs1167604782, COSV99401485; called by muse, mutect2, varscan2
- PMPCB | c.440C>G p.S147C | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99971435; called by muse, mutect2, varscan2
- PNISR | c.2036A>T p.K679M | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); catalogued as COSV100984428; called by muse, mutect2, varscan2
- POP1 | c.984G>T p.W328C | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100856098; called by muse, mutect2, varscan2
- POU2F3 | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99501503; called by muse, mutect2
- PRAG1 | c.4132G>T p.E1378* | Nonsense Mutation (SNP) | VAF 64/196 reads (33%) | catalogued as rs1360131945, COSV100422777; called by muse, mutect2, varscan2
- PRB3 | c.698G>C p.G233A (on ENST00000381842; = p.G275A on NM_006249.5) | Missense Mutation (SNP) | VAF 84/632 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV99686053; called by muse, mutect2, varscan2
- PRDM9 | c.879G>T p.W293C | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745910443, COSV99691215; called by muse, mutect2, varscan2
- PRKD2 | c.1270A>G p.K424E | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99354630; called by muse, mutect2
- PRKG1 | c.1993G>C p.D665H | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100907490; called by muse, mutect2, varscan2
- PRPF38B | c.691C>G p.Q231E | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.099); catalogued as COSV64224317; called by muse, mutect2, varscan2
- PSKH2 | c.686T>C p.I229T | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV99405387; called by muse, mutect2
- PTPRC | c.1429C>A p.H477N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100723148; called by mutect2, varscan2
- PTPRK | c.2030G>A p.G677E | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV63890368; called by muse, mutect2
- PWWP2B | c.81C>A p.C27* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100535929; called by muse, mutect2
- PZP | c.1652C>A p.S551Y | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99739341; called by muse, mutect2
- PZP | c.1651T>A p.S551T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.1); catalogued as COSV99739348; called by muse, mutect2
- RAB26 | c.745C>G p.R249G | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV99270004; called by muse, mutect2, varscan2
- RAB28 | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99986432; called by muse, mutect2, varscan2
- RAC2 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.106); catalogued as COSV99969655; called by muse, mutect2
- RANBP6 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV99424392; called by muse, mutect2, varscan2
- RBBP8 | c.2687A>C p.K896T | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100507648; called by muse, mutect2
- RBM10 | c.1507G>C p.A503P | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.649); catalogued as COSV100238266; called by muse, mutect2, varscan2
- REG1B | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100521524, COSV59304787; called by muse, mutect2, varscan2
- RIMBP2 | c.1937G>T p.G646V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99900418; called by muse, mutect2, varscan2
- RIMS2 | c.1193C>G p.S398* (on ENST00000666250 / NM_001348490.2; = p.S206* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | catalogued as COSV99196711; called by muse, mutect2, varscan2
- RIMS2 | c.2449C>A p.L817I (on ENST00000666250 / NM_001348490.2; = p.L625I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51698166; called by muse, mutect2, varscan2
- RNF26 | c.464G>A p.C155Y | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV100264926; called by muse, mutect2, varscan2
- RPAP2 | c.1058G>T p.S353I | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as COSV101532188; called by muse, mutect2, varscan2
- RREB1 | c.1762G>T p.G588C | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV58563971; called by muse, mutect2, varscan2
- RRP12 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV100213433; called by muse, mutect2, varscan2
- RUVBL1 | c.392A>T p.Y131F | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.181); catalogued as COSV100494266; called by muse, mutect2
- RYR3 | c.6550G>A p.D2184N | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101214404; called by muse, mutect2
- RYR3 | c.13622C>A p.T4541K (on ENST00000389232; = p.T4542K on NM_001036.6) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101214405; called by muse, mutect2, varscan2
- SAA2-SAA4 | c.406G>T p.G136* | Nonsense Mutation (SNP) | VAF 48/233 reads (21%) | catalogued as COSV53447905, COSV99541666; called by muse, mutect2, varscan2
- SATB2 | c.262C>G p.R88G | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV53484706, COSV99612569, COSV99612749; called by muse, mutect2, varscan2
- SCN3B | c.268G>C p.G90R | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as COSV100173854; called by muse, mutect2, varscan2
- SCNN1B | c.1771C>T p.Q591* | Nonsense Mutation (SNP) | VAF 13/114 reads (11%) | catalogued as CM941274, COSV56303749; called by muse, mutect2
- SDHA | c.420C>G p.H140Q | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.55); catalogued as rs747232441, COSV99372159; called by muse, mutect2
- SEC24D | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99756759; called by muse, mutect2, varscan2
- SEMA3E | c.2278C>A p.R760S | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.422); catalogued as rs1324637406, COSV100319557, COSV57082594; called by muse, mutect2, varscan2
- SEPHS1 | c.663G>A p.W221* | Nonsense Mutation (SNP) | VAF 12/99 reads (12%) | catalogued as COSV100526027; called by muse, mutect2, varscan2
- SERPINB13 | c.771+1G>A p.X257_splice | Splice Site (SNP) | VAF 26/127 reads (20%) | catalogued as COSV99501269; called by muse, mutect2, varscan2
- SIGLEC1 | c.142G>C p.D48H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV99170731; called by muse, mutect2, varscan2
- SKI | c.710A>G p.Y237C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101049617; called by muse, mutect2, varscan2
- SLC10A3 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as COSV99682227; called by muse, mutect2, varscan2
- SLC14A2 | c.824C>A p.T275K | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV99676152; called by muse, mutect2, varscan2
- SLC16A1 | c.190A>G p.I64V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.669); catalogued as rs761211321, COSV100856069; called by muse, mutect2, varscan2
- SLC17A3 | c.1201C>T p.L401F | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV100645445; called by muse, mutect2, varscan2
- SLC17A6 | c.736T>C p.F246L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54135616, COSV99582356; called by muse, mutect2, varscan2
- SLC19A2 | c.1058A>G p.Y353C | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.248); catalogued as COSV99357129; called by muse, mutect2, varscan2
- SLC22A9 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.123); catalogued as COSV99655361; called by muse, mutect2, varscan2
- SLC25A3 | c.6C>G p.F2L | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs778865084, COSV99499623; called by muse, mutect2, varscan2
- SLC25A5 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.901); catalogued as COSV58625545; called by muse, mutect2, varscan2
- SLC26A7 | c.267T>G p.I89M | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748126263, COSV99404283; called by muse, mutect2, varscan2
- SLC39A12 | c.1222G>T p.A408S | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101070142; called by muse, mutect2, varscan2
- SLC4A10 | c.2720G>T p.R907L (on ENST00000446997 / NM_001354461.2; = p.R877L on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV55786050; called by muse, mutect2, varscan2
- SLC6A8 | c.1530G>T p.M510I | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV99466266; called by muse, mutect2, varscan2
- SLCO1A2 | c.412C>A p.Q138K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV100262642; called by muse, mutect2, varscan2
- SLCO4C1 | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100195790; called by muse, mutect2, varscan2
- SLIT3 | c.2303C>A p.P768H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100269690; called by muse, mutect2, varscan2
- SMC2 | c.2175G>T p.E725D | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV99659669; called by muse, mutect2, varscan2
- SMPD4 | c.2087C>T p.P696L (on ENST00000409031 / NM_017951.4; = p.P667L on NM_017751.4) | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs1023825789, COSV100302746; called by muse, mutect2, varscan2
- SNAP25 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); catalogued as rs751046094, COSV99655322; called by muse, mutect2
- SP7 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.028); catalogued as COSV100382088, COSV100382107; called by muse, mutect2
- SPATA16 | c.930G>C p.W310C | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100651613; called by muse, mutect2, varscan2
- SPHKAP | c.3607G>C p.E1203Q | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs760142985, COSV100764524, COSV60888996; called by muse, mutect2, varscan2
- SPOPL | c.287G>A p.S96N | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99699768; called by muse, mutect2, varscan2
- SPPL2A | c.227C>G p.S76C | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99961814; called by muse, mutect2, varscan2
- SPTBN4 | c.6960G>T p.K2320N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV100152047; called by muse, mutect2, varscan2
- SRPK2 | c.923C>A p.S308* | Nonsense Mutation (SNP) | VAF 12/143 reads (8%) | catalogued as COSV100624330, COSV61963906; called by muse, mutect2
- SRPX2 | c.213C>G p.C71W | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759928016, COSV100884061; called by muse, mutect2, varscan2
- STAP1 | c.563C>A p.T188N | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.958); catalogued as COSV99609663; called by muse, mutect2, varscan2
- STARD8 | c.105G>A p.W35* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99367600; called by muse, mutect2, varscan2
- STKLD1 | c.920C>G p.S307C | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV100912204; called by muse, mutect2
- SUCO | c.2804A>T p.Y935F | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99743740; called by muse, mutect2, varscan2
- SVEP1 | c.10051C>A p.L3351I | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as rs1285363139, COSV99929741; called by muse, mutect2, varscan2
- SVEP1 | c.8404G>A p.D2802N | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV99929743; called by muse, mutect2, varscan2
- SVEP1 | c.3053G>T p.C1018F | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100238986; called by muse, mutect2, varscan2
- SYNE1 | c.495C>A p.S165R (on ENST00000367255 / NM_182961.4; = p.S172R on NM_033071.3) | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs567913785, COSV99577642; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF6 | c.1769C>T p.T590I | Missense Mutation (SNP) | VAF 68/251 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100612860; called by muse, mutect2, varscan2
- TBX10 | c.620G>A p.S207N | Missense Mutation (SNP) | VAF 50/340 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.155); catalogued as rs1216261036, COSV100039900; called by muse, mutect2, varscan2
- TBX2 | c.963C>A p.D321E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.997); catalogued as COSV99539140; called by muse, mutect2, varscan2
- TBX20 | c.637C>A p.L213M | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.314); catalogued as COSV101282421; called by muse, mutect2, varscan2
- TCEAL1 | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); catalogued as COSV101010132; called by muse, mutect2, varscan2
- TENM1 | c.4330A>G p.T1444A | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV100950873; called by muse, mutect2
- TMC1 | c.1761C>A p.I587= | Splice Region (SNP) | VAF 41/124 reads (33%) | catalogued as COSV99920454; called by muse, mutect2, varscan2
- TMC3 | c.679C>A p.P227T | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100846016; called by muse, mutect2, varscan2
- TMEM108 | c.1295G>T p.R432L | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs757969231, COSV100419223, COSV100419571; called by muse, mutect2, varscan2
- TMEM119 | c.563G>T p.R188M | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV101219544; called by muse, mutect2, varscan2
- TMEM151A | c.413T>A p.L138Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as COSV100517065; called by muse, mutect2
- TMEM196 | c.313C>A p.L105I | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV101337523; called by muse, mutect2, varscan2
- TMPRSS11A | c.603G>A p.W201* | Nonsense Mutation (SNP) | VAF 12/143 reads (8%) | catalogued as COSV100602832; called by muse, mutect2
- TNFAIP2 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as rs1012685443, COSV100281100; called by muse, mutect2
- TNKS1BP1 | c.2116G>T p.E706* | Nonsense Mutation (SNP) | VAF 37/131 reads (28%) | catalogued as COSV100836262; called by muse, mutect2, varscan2
- TONSL | c.2563G>C p.D855H | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV101340308; called by muse, mutect2
- TRAF5 | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99807617; called by muse, mutect2, varscan2
- TREH | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.057); catalogued as COSV99874785; called by muse, mutect2
- TRIM44 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV100195561; called by muse, mutect2
- TRIM58 | c.552G>C p.L184F | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.142); catalogued as COSV100825281; called by muse, mutect2
- TRIM6-TRIM34 | c.1028G>T p.G343V | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV100709204; called by muse, mutect2, varscan2
- TRPC1 | c.89A>T p.E30V | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99859311; called by muse, mutect2, varscan2
- TTN | c.101080C>T p.H33694Y (on ENST00000591111; = p.H26270Y on NM_003319.4) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | PolyPhen probably damaging (0.994); catalogued as COSV100621204, COSV100628836; called by muse, mutect2, varscan2
- TTN | c.90224C>A p.T30075N (on ENST00000591111; = p.T22651N on NM_003319.4) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | PolyPhen possibly damaging (0.862); catalogued as rs879097606, COSV100628838; called by muse, mutect2, varscan2
- TTN | c.81170G>A p.W27057* (on ENST00000591111; = p.W19633* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100628841, COSV59989443; called by muse, mutect2, varscan2
- TTN | c.74201C>A p.S24734Y (on ENST00000591111; = p.S17310Y on NM_003319.4) | Missense Mutation (SNP) | VAF 28/200 reads (14%) | PolyPhen probably damaging (0.998); catalogued as COSV100628842; called by muse, mutect2, varscan2
- TTN | c.29638C>A p.P9880T (on ENST00000591111; = p.P8953T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/87 reads (7%) | PolyPhen probably damaging (0.994); catalogued as COSV100628845; called by muse, mutect2
- TTN | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 23/196 reads (12%) | PolyPhen benign (0.325); catalogued as rs1429805491, COSV100628846; called by muse, mutect2, varscan2
- TYRO3 | c.1056A>T p.E352D | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV55480369; called by muse, mutect2, varscan2
- UBR5 | c.4568C>T p.P1523L | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.1); catalogued as COSV99642278; called by muse, mutect2, varscan2
- UBXN2B | c.834G>T p.R278S | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV68309695; called by muse, mutect2, varscan2
- UCHL5 | c.844A>T p.K282* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100815500; called by muse, mutect2
- UHRF1BP1L | c.2270G>A p.S757N | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs1030799527, COSV99692119; called by muse, mutect2, varscan2
- UNC13B | c.3893G>T p.R1298L | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV101037272; called by muse, mutect2, varscan2
- UNC5D | c.1415C>A p.S472Y | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.343); catalogued as COSV99778547; called by muse, mutect2, varscan2
- UROC1 | c.620C>A p.A207E | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99332336; called by muse, mutect2, varscan2
- USH2A | c.8144T>A p.V2715E | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100242221; called by muse, mutect2, varscan2
- UTP20 | c.5257A>G p.K1753E | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99882500; called by muse, mutect2, varscan2
- VAC14 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs774953912, COSV99935034; called by muse, mutect2, varscan2
- VPS35L | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99220705; called by muse, mutect2, varscan2
- VPS50 | c.2171A>G p.Y724C | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV100004540; called by muse, mutect2
- WBP1L | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 22/120 reads (18%) | catalogued as COSV100882521; called by muse, mutect2
- WNT1 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV53295128; called by muse, mutect2
- WNT5B | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as COSV100148655; called by muse, mutect2
- WSB2 | c.180G>T p.Q60H | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.135); catalogued as COSV100199491; called by muse, mutect2, varscan2
- WSCD2 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 33/319 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs755142745, COSV99775217; called by muse, mutect2, varscan2
- ZBBX | c.1690A>G p.S564G | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100284907; called by muse, mutect2, varscan2
- ZBTB18 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100700066, COSV100700222; called by muse, mutect2, varscan2
- ZBTB33 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100434318; called by muse, mutect2, varscan2
- ZDBF2 | c.5903C>A p.P1968Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100985508; called by muse, mutect2, varscan2
- ZDBF2 | c.6701T>C p.L2234S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV100985509; called by muse, mutect2, varscan2
- ZFC3H1 | c.2086C>T p.R696* | Nonsense Mutation (SNP) | VAF 10/98 reads (10%) | catalogued as COSV101110680; called by mutect2, varscan2
- ZFP42 | c.776A>G p.D259G | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV100479152; called by muse, mutect2, varscan2
- ZMAT1 | c.1906C>A p.L636I | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1177604680, COSV65658938; called by muse, mutect2, varscan2
- ZNF318 | c.881C>G p.S294* | Nonsense Mutation (SNP) | VAF 21/72 reads (29%) | catalogued as COSV100546500; called by muse, mutect2, varscan2
- ZNF423 | c.1005G>T p.M335I (on ENST00000563137 / NM_001379286.1; = p.M327I on NM_015069.4) | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV99283663; called by muse, mutect2, varscan2
- ZNF713 | c.286G>A p.E96K (on ENST00000633730 / NM_001366796.2; = p.E109K on NM_182633.3) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs775723451, COSV101448753; called by muse, varscan2
- ZNF783 | c.694C>A p.H232N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV100954297; called by muse, mutect2, varscan2
- ZNF804A | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1430196185, COSV100170037; called by muse, mutect2, varscan2
- ZNF831 | c.2839C>G p.Q947E | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as rs756845233, COSV100926240, COSV64039068; called by muse, mutect2, varscan2
- CCL15 | c.76G>C p.D26H | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CDC123 | c.75-2del p.X25_splice | Splice Site (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel
- CSMD3 | c.10873G>C p.G3625R (on ENST00000297405 / NM_001363185.1; = p.G3456R on NM_052900.3) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.106); called by muse, mutect2
- DNAH9 | c.4021del p.R1341Gfs*27 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- DTX3L | c.779_780del p.R260Ifs*6 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | called by mutect2, pindel, varscan2
- IGHG3 | c.1307C>A p.P436H | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV1-18 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- IGKV3D-20 | c.338del p.G113Vfs*? | Frame Shift Del (DEL) | VAF 19/110 reads (17%) | called by mutect2, pindel
- KMT2D | c.7824_7838delinsG p.P2609Vfs*41 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by pindel, varscan2*
- MYO7B | c.1194del p.F398Lfs*107 | Frame Shift Del (DEL) | VAF 18/172 reads (10%) | called by mutect2, pindel, varscan2
- PLXNB3 | c.919_920insG p.P307Rfs*57 | Frame Shift Ins (INS) | VAF 2/10 reads (20%) | called by muse*, mutect2
- PRAMEF20 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 48/401 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SALL4 | c.168_170del p.S57del | In Frame Del (DEL) | VAF 42/141 reads (30%) | called by mutect2, pindel, varscan2
- SERPINA13P | n.1111C>A | Splice Region (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- TBC1D8B | c.1393T>A p.F465I | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- WASHC2A | c.2904G>T p.L968F | Missense Mutation (SNP) | VAF 36/248 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, varscan2
- ZNF2 | c.1142_1155del p.P381Rfs*7 (on ENST00000611147 / NM_001291605.2; = p.P368Rfs*7 on NM_021088.4) | Frame Shift Del (DEL) | VAF 28/209 reads (13%) | called by mutect2, pindel
- ZNF605 | c.404G>T p.R135I | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- ADAM12 | c.1104C>T p.S368= | Silent (SNP) | VAF 43/169 reads (25%) | catalogued as COSV100901445; called by muse, mutect2, varscan2
- ADAMTS9 | c.5451G>A p.K1817= | Silent (SNP) | VAF 23/125 reads (18%) | catalogued as rs776361810, COSV99900144; called by muse, mutect2, varscan2
- ADCY10 | c.2001C>T p.F667= | Silent (SNP) | VAF 33/208 reads (16%) | catalogued as COSV63245656; called by muse, mutect2, varscan2
- ADGRG4 | c.3411C>A p.T1137= | Silent (SNP) | VAF 24/225 reads (11%) | catalogued as COSV99796640; called by muse, mutect2, varscan2
- AEBP1 | c.3135C>A p.G1045= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as COSV99789098; called by muse, mutect2, varscan2
- AHNAK2 | c.6696C>G p.L2232= | Silent (SNP) | VAF 34/398 reads (9%) | catalogued as COSV100318865; called by muse, mutect2
- AL592490.1 | c.456G>T p.L152= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV101308280; called by muse, mutect2, varscan2
- ANGPT1 | c.1496G>A p.*499= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as COSV99864092; called by muse, mutect2
- ANKRD30A | c.354G>A p.Q118= (on ENST00000611781; = p.Q62= on NM_052997.2) | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV100654415; called by muse, mutect2
- ASIC4 | c.9C>A p.I3= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as COSV100761919; called by muse, mutect2, varscan2
- ATP13A2 | c.3537G>A p.L1179= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100454416; called by muse, mutect2, varscan2
- ATP13A4 | c.2583G>T p.V861= | Silent (SNP) | VAF 46/98 reads (47%) | catalogued as COSV100710728; called by muse, mutect2, varscan2
- ATP13A5 | c.2175G>A p.T725= | Silent (SNP) | VAF 24/292 reads (8%) | catalogued as rs1227845655, COSV100665705; called by muse, mutect2
- BDKRB2 | c.78C>T p.A26= | Silent (SNP) | VAF 229/612 reads (37%) | catalogued as rs201408953, COSV60014210; called by muse, mutect2, varscan2
- BRSK2 | c.1692C>A p.V564= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- C5AR2 | c.978C>G p.S326= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV99953889; called by muse, mutect2, varscan2
- CA12 | c.912C>T p.I304= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV51604770; called by muse, mutect2
- CACNG7 | c.795G>A p.P265= | Silent (SNP) | VAF 58/416 reads (14%) | catalogued as rs781713330, COSV99712287; called by muse, mutect2, varscan2
- CASZ1 | c.699G>A p.R233= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV100682139; called by muse, mutect2, varscan2
- CCT8L2 | c.288C>A p.T96= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as COSV100743101; called by muse, mutect2, varscan2
- CD33 | c.978A>T p.S326= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV99220771; called by muse, mutect2, varscan2
- CDH10 | c.267C>A p.L89= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100053029; called by muse, mutect2, varscan2
- CDH12 | c.2139A>T p.I713= | Silent (SNP) | VAF 22/141 reads (16%) | catalogued as COSV101203288; called by muse, mutect2, varscan2
- CDK2AP1 | c.159T>A p.T53= | Silent (SNP) | VAF 24/202 reads (12%) | catalogued as COSV99908592; called by muse, mutect2, varscan2
- CHIA | c.621C>A p.I207= (on ENST00000343320; = p.I99= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 37/111 reads (33%) | catalogued as COSV100588831, COSV58478460; called by muse, mutect2, varscan2
- CHRNA10 | c.951C>T p.I317= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as rs773268867, COSV99167250; called by muse, mutect2, varscan2
- CLEC4C | c.633C>A p.I211= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as rs142052046, COSV100665432, COSV100665568; called by muse, mutect2, varscan2
- CLTCL1 | c.4540C>T p.L1514= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as rs547779543, COSV54227691, COSV99595839; called by muse, mutect2
- CNTNAP4 | c.426G>T p.V142= | Silent (SNP) | VAF 40/207 reads (19%) | catalogued as COSV100273241; called by muse, mutect2, varscan2
- COL4A5 | c.4938C>T p.S1646= | Silent (SNP) | VAF 15/180 reads (8%) | catalogued as COSV100089695, COSV60369801; called by muse, mutect2
- CSN2 | c.438C>A p.L146= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV100778833; called by muse, mutect2, varscan2
- CTNNA2 | c.2103G>T p.V701= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV100561969; called by muse, mutect2, varscan2
- DAAM2 | c.460T>C p.L154= | Silent (SNP) | VAF 55/171 reads (32%) | catalogued as COSV99226913; called by muse, mutect2, varscan2
- DAAM2 | c.2034C>A p.A678= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99226917; called by muse, mutect2, varscan2
- DCAF4L2 | c.1140G>T p.G380= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as rs1437609272, COSV100151274; called by muse, mutect2, varscan2
- DCAF4L2 | c.765T>C p.C255= | Silent (SNP) | VAF 42/169 reads (25%) | catalogued as COSV100151275, COSV60479254; called by muse, mutect2, varscan2
- DCP1B | c.1815C>G p.L605= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV99767917, COSV99767922; called by muse, mutect2, varscan2
- DEPDC4 | c.189A>G p.L63= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs371099609, COSV100147416; called by muse, mutect2
- DIDO1 | c.5409G>A p.Q1803= | Silent (SNP) | VAF 41/254 reads (16%) | catalogued as COSV56617298, COSV56619349, COSV56637594; called by muse, mutect2, varscan2
- DLX5 | c.651G>A p.S217= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as rs1481006632, COSV99756667; called by muse, mutect2, varscan2
- DZIP3 | c.2067G>A p.R689= | Silent (SNP) | VAF 15/218 reads (7%) | catalogued as COSV100848070; called by muse, mutect2
- ENPP4 | c.93A>T p.V31= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV100320458; called by muse, mutect2, varscan2
- EPG5 | c.6879G>T p.R2293= | Silent (SNP) | VAF 19/138 reads (14%) | catalogued as COSV99958051; called by muse, mutect2, varscan2
- EPHA1 | c.399G>T p.V133= | Silent (SNP) | VAF 66/220 reads (30%) | catalogued as COSV51971142; called by muse, mutect2, varscan2
- F13A1 | c.2118G>A p.L706= | Silent (SNP) | VAF 24/152 reads (16%) | catalogued as COSV99343866, COSV99344179; called by muse, mutect2, varscan2
- F8 | c.318A>T p.T106= | Silent (SNP) | VAF 64/234 reads (27%) | catalogued as COSV100811906; called by muse, mutect2, varscan2
- FBXW11 | c.771A>G p.L257= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs1313737853, COSV99441446; called by muse, mutect2, varscan2
- FILIP1 | c.3294A>T p.T1098= | Silent (SNP) | VAF 49/166 reads (30%) | catalogued as COSV99386073; called by muse, mutect2, varscan2
- FYN | c.222G>A p.G74= | Silent (SNP) | VAF 11/155 reads (7%) | catalogued as rs772105415, COSV99992444; called by muse, mutect2
- GPATCH2L | c.1011T>A p.T337= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as COSV99833914; called by muse, mutect2, varscan2
- GPR171 | c.693C>A p.G231= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV99854573; called by muse, mutect2, varscan2
- GRID1 | c.2733C>A p.T911= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV100026353; called by muse, mutect2
- GRXCR2 | c.369C>A p.I123= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV100940033, COSV65061713; called by muse, mutect2, varscan2
- HADH | c.858A>G p.L286= | Silent (SNP) | VAF 73/182 reads (40%) | catalogued as COSV100531555; called by muse, mutect2, varscan2
- HBG2 | c.339C>A p.T113= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as rs201444721, COSV100400696; called by muse, varscan2
- ICAM4 | c.72G>T p.L24= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99321127; called by muse, mutect2, varscan2
- IGKV1-6 | c.93C>A p.S31= | Silent (SNP) | VAF 65/270 reads (24%) | called by muse, mutect2, varscan2
- IGKV3-11 | c.300T>A p.P100= | Silent (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- ISYNA1 | c.172C>A p.R58= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs542513210, COSV99443728; called by muse, varscan2
- ITGB1 | c.15A>T p.P5= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs780637452, COSV100171983; called by mutect2, varscan2
- ITIH6 | c.3852G>A p.R1284= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs1474395896, COSV99513938; called by muse, mutect2, varscan2
- KCNA4 | c.231G>A p.Q77= | Silent (SNP) | VAF 42/141 reads (30%) | catalogued as COSV100069241, COSV60252656; called by muse, mutect2, varscan2
- KCNC2 | c.360C>T p.T120= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV100129516; called by muse, varscan2
- KCTD18 | c.99C>T p.F33= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV100728959; called by muse, mutect2, varscan2
- KIAA1217 | c.2868G>T p.V956= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV100287244; called by muse, mutect2, varscan2
- KLHL22 | c.1380G>A p.L460= | Silent (SNP) | VAF 38/420 reads (9%) | catalogued as COSV100186237; called by muse, mutect2
- KRT76 | c.480A>T p.V160= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV100196508, COSV60120064; called by muse, mutect2, varscan2
- LAMC2 | c.3339C>T p.L1113= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as COSV51461554; called by muse, mutect2, varscan2
- LARP7 | c.583A>C p.R195= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV100135316; called by muse, mutect2, varscan2
- LONRF3 | c.1716G>A p.L572= (on ENST00000371628 / NM_001031855.3; = p.L531= on NM_024778.5) | Silent (SNP) | VAF 25/190 reads (13%) | catalogued as rs144808950, COSV100504668; called by muse, mutect2, varscan2
- LPO | c.2031C>G p.T677= | Silent (SNP) | VAF 55/143 reads (38%) | catalogued as COSV99229364; called by muse, mutect2, varscan2
- LRBA | c.6495C>T p.F2165= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100842069; called by muse, mutect2
- LRP1B | c.12939G>T p.P4313= | Silent (SNP) | VAF 71/295 reads (24%) | catalogued as COSV101260542; called by muse, mutect2, varscan2
- MAMLD1 | c.390G>A p.L130= | Silent (SNP) | VAF 54/164 reads (33%) | catalogued as COSV99476553; called by muse, mutect2, varscan2
- MCRS1 | c.243A>T p.P81= | Silent (SNP) | VAF 82/372 reads (22%) | catalogued as COSV100657425; called by muse, mutect2, varscan2
- MEIS2 | c.159G>T p.A53= (on ENST00000561208 / NM_170675.5; = p.A40= on NM_002399.3) | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as rs748998918, COSV54931781, COSV54940118, COSV99577268; called by muse, mutect2, varscan2
- MID2 | c.438G>T p.P146= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV99465543; called by muse, mutect2, varscan2
- MMP9 | c.1218G>T p.A406= | Silent (SNP) | VAF 43/172 reads (25%) | catalogued as COSV63433938; called by muse, mutect2, varscan2
- MORC1 | c.1017T>A p.L339= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV99227698; called by muse, mutect2, varscan2
- MS4A1 | c.90C>G p.L30= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV100619427; called by muse, mutect2, varscan2
- MTCL1 | c.5016C>T p.G1672= (on ENST00000306329 / NM_001378206.1; = p.G1353= on NM_015210.4) | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs751030645, COSV60409101; called by muse, mutect2, varscan2
- MYH2 | c.975C>T p.S325= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV99820915; called by muse, mutect2, varscan2
- NKX6-1 | c.1047C>T p.S349= | Silent (SNP) | VAF 42/157 reads (27%) | catalogued as COSV55684154, COSV99880191; called by muse, mutect2, varscan2
- NOTCH1 | c.6693C>T p.L2231= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV53072321, COSV99491511; called by muse, mutect2, varscan2
- NPHP4 | c.903G>T p.P301= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100976709, COSV100977119; called by muse, mutect2, varscan2
- NRXN2 | c.3507C>T p.F1169= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV99635674; called by muse, mutect2
- OR11H1 | c.888C>G p.L296= | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as rs1319668276; called by mutect2, varscan2
- OR4D10 | c.555C>A p.L185= | Silent (SNP) | VAF 44/162 reads (27%) | catalogued as COSV101597030; called by muse, mutect2, varscan2
- OR4K17 | c.321G>T p.L107= | Silent (SNP) | VAF 35/136 reads (26%) | catalogued as COSV100210794; called by muse, mutect2, varscan2
- PCDHA3 | c.1116C>T p.I372= | Silent (SNP) | VAF 21/148 reads (14%) | catalogued as rs368766260; called by muse, mutect2, varscan2
- PDCD4 | c.1011A>G p.E337= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as rs147334980; called by muse, mutect2, varscan2
- PJA1 | c.1815G>C p.G605= (on ENST00000361478 / NM_145119.4; = p.G417= on NM_022368.5) | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV100824805; called by muse, mutect2, varscan2
- PLXNB3 | c.2721G>T p.R907= | Silent (SNP) | VAF 28/349 reads (8%) | catalogued as COSV100737889; called by muse, mutect2
- POLQ | c.2058A>G p.L686= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV99952925; called by muse, mutect2, varscan2
- PRR16 | c.834C>T p.I278= (on ENST00000407149 / NM_001300783.2; = p.I255= on NM_016644.2) | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV101087946; called by muse, mutect2, varscan2
- PRSS16 | c.1075A>C p.R359= | Silent (SNP) | VAF 39/138 reads (28%) | catalogued as COSV100041977; called by muse, mutect2, varscan2
- PTPRM | c.2151C>G p.V717= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100160204; called by muse, mutect2
- PUS1 | c.984G>T p.A328= | Silent (SNP) | VAF 42/147 reads (29%) | catalogued as COSV100435285; called by muse, mutect2, varscan2
- RAB41 | c.138C>G p.S46= (on ENST00000374473 / NM_001363807.1; = p.S45= on NM_001032726.3) | Silent (SNP) | VAF 6/105 reads (6%) | called by muse, mutect2
- RABGAP1 | c.345A>G p.Q115= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs1331903219, COSV100438676; called by muse, mutect2, varscan2
- RCOR1 | c.1014G>A p.L338= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as COSV99217777; called by muse, mutect2
- RIMS2 | c.2448C>A p.T816= (on ENST00000666250 / NM_001348490.2; = p.T624= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 44/206 reads (21%) | catalogued as COSV99196819; called by muse, mutect2, varscan2
- RPRD1A | c.714G>A p.K238= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as COSV100036421; called by muse, mutect2, varscan2
- RTL9 | c.1122A>T p.P374= | Silent (SNP) | VAF 76/599 reads (13%) | catalogued as COSV101511791; called by muse, mutect2, varscan2
- S1PR1 | c.360G>T p.R120= | Silent (SNP) | VAF 19/140 reads (14%) | catalogued as COSV100541671; called by muse, mutect2, varscan2
- SAMD9 | c.4743A>T p.P1581= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as COSV101180367, COSV66075111; called by muse, mutect2, varscan2
- SLC12A1 | c.2136C>A p.I712= | Silent (SNP) | VAF 12/147 reads (8%) | catalogued as COSV101119346; called by muse, mutect2
- SLC7A14 | c.18C>G p.T6= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV99200929; called by muse, mutect2
- SLIT3 | c.2304C>A p.P768= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100269689, COSV60626163; called by muse, mutect2, varscan2
- SNN | c.171G>A p.K57= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV99298367; called by muse, mutect2
- SOX10 | c.564G>A p.A188= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as rs574900029, COSV100704199; called by muse, mutect2, varscan2
- SPEF2 | c.2082G>C p.L694= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV100608823; called by muse, mutect2
- SYNE1 | c.10767T>G p.T3589= (on ENST00000367255 / NM_182961.4; = p.T3596= on NM_033071.3) | Silent (SNP) | VAF 17/129 reads (13%) | catalogued as COSV99577636; called by muse, mutect2, varscan2
- TFEB | c.1146C>G p.P382= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs779208846, COSV100026459; called by muse, mutect2, varscan2
- TMC5 | c.483G>T p.P161= | Silent (SNP) | VAF 29/242 reads (12%) | catalogued as rs771364798, COSV101196912, COSV66869354; called by muse, mutect2, varscan2
- TMTC3 | c.1230G>A p.L410= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV99898672; called by muse, mutect2, varscan2
- TNR | c.1665C>T p.P555= | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as COSV99691434; called by muse, mutect2, varscan2
- TOR1AIP1 | c.319C>A p.R107= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV99621651, COSV99621781; called by muse, mutect2
- TRIM51 | c.615C>T p.G205= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as rs141719000, COSV55270137; called by muse, mutect2, varscan2
- TRMT2B | c.447C>A p.I149= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV100105656; called by muse, mutect2
- TRPM2 | c.873C>G p.T291= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV100309287; called by muse, mutect2, varscan2
- TSPYL5 | c.18G>T p.R6= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100439127; called by muse, mutect2, varscan2
- TUBB4B | c.876G>A p.Q292= | Silent (SNP) | VAF 20/186 reads (11%) | catalogued as COSV100458177; called by muse, mutect2
- USH2A | c.6291C>A p.I2097= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV100242222; called by muse, mutect2, varscan2
- USP4 | c.261A>G p.L87= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV99649721; called by muse, mutect2, varscan2
- VPS28 | c.45G>A p.G15= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99465934; called by muse, mutect2
- XPO1 | c.744C>T p.S248= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV101294311; called by muse, mutect2, varscan2
- ZC3H12B | c.693T>A p.T231= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100162017; called by muse, mutect2, varscan2
- ZFAT | c.1554G>C p.L518= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100914610, COSV100914920; called by muse, mutect2, varscan2
- ZFHX4 | c.8745C>A p.S2915= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs752886772, COSV50664255, COSV99267281; called by muse, mutect2, varscan2
- ZNF165 | c.651A>G p.S217= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as rs1466173754, COSV101056070; called by muse, mutect2, varscan2
- ZNF516 | c.651C>T p.S217= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV101487364; called by muse, mutect2, varscan2
- ZNF573 | c.849T>C p.F283= (on ENST00000536220 / NM_001172692.1; = p.F225= on NM_152360.3) | Silent (SNP) | VAF 50/144 reads (35%) | catalogued as rs1244195840, COSV100265833; called by muse, mutect2, varscan2
- ZNF644 | c.3537G>A p.R1179= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV100494712; called by muse, mutect2, varscan2
- ZSCAN32 | c.1092G>A p.R364= (on ENST00000396846; = p.R385= on NM_017810.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as rs779618451, COSV100514549; called by muse, mutect2, varscan2
- ZXDB | c.1884G>T p.V628= | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as COSV100886049; called by muse, mutect2, varscan2
- AL590867.2 | n.52C>G | RNA (SNP) | VAF 20/184 reads (11%) | catalogued as rs375853555; called by muse, mutect2, varscan2
- C1QTNF3 | c.84+75G>A | Intron (SNP) | VAF 35/299 reads (12%) | catalogued as COSV51467541; called by muse, mutect2, varscan2
- CAPS2 | c.1670-2654T>A | Intron (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100158229; called by muse, mutect2, varscan2
- COL9A1 | c.781-74T>A | Intron (SNP) | VAF 15/63 reads (24%) | catalogued as COSV100295546; called by muse, mutect2, varscan2
- DTNA | c.1662+2091A>C | Intron (SNP) | VAF 38/101 reads (38%) | catalogued as COSV99315180; called by muse, mutect2, varscan2
- FOLH1B | n.1372G>T | RNA (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- GNA12 | c.310-19212G>T | Intron (SNP) | VAF 31/100 reads (31%) | catalogued as COSV99283001; called by muse, mutect2, varscan2
- HERC2P3 | n.768G>T | RNA (SNP) | VAF 30/241 reads (12%) | called by muse, mutect2, varscan2
- MAGEA5 | n.116T>G | RNA (SNP) | VAF 18/137 reads (13%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5146C>A | Intron (SNP) | VAF 36/194 reads (19%) | catalogued as COSV99962816; called by muse, mutect2, varscan2
- MIDEAS | c.-1C>T | 5'UTR (SNP) | VAF 38/99 reads (38%) | catalogued as COSV99679218; called by muse, mutect2, varscan2
- PDGFB | c.63+3046C>A | Intron (SNP) | VAF 12/100 reads (12%) | catalogued as COSV58648514, COSV58649386, COSV58650156; called by muse, varscan2
- PITPNM1 | c.-1G>C | 5'UTR (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100039466; called by muse, mutect2
- RASSF1 | c.369+595G>A | Intron (SNP) | VAF 9/94 reads (10%) | catalogued as COSV99205926; called by muse, mutect2, varscan2
- RPP38 | chr10:15096526 T>A | 5'Flank (SNP) | VAF 22/119 reads (18%) | called by muse, mutect2, varscan2
- SLC22A20P | n.1335A>T | RNA (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- SNORD115-18 | n.5C>T | RNA (SNP) | VAF 36/310 reads (12%) | catalogued as rs765188076; called by muse, mutect2, varscan2
- SNORD115-36 | n.44G>T | RNA (SNP) | VAF 54/466 reads (12%) | catalogued as rs775538481; called by muse, mutect2, varscan2
- SSPOP | n.6586G>T | RNA (SNP) | VAF 17/120 reads (14%) | catalogued as COSV100022972; called by muse, mutect2, varscan2
- SYNPO | chr5:150657040 C>T | 3'Flank (SNP) | VAF 5/25 reads (20%) | catalogued as rs530746865, COSV51739771, COSV99770883; called by muse, mutect2
- UNG | c.133-44G>T | Intron (SNP) | VAF 28/132 reads (21%) | catalogued as COSV99655454; called by muse, mutect2, varscan2
- Y_RNA | chr14:50091545 C>A | 3'Flank (SNP) | VAF 21/51 reads (41%) | catalogued as rs372885333; called by muse, mutect2, varscan2
